Somatic mutation profile of tumor specimen TCGA-T2-A6X2-01A (aliquot TCGA-T2-A6X2-01A-12D-A34J-08) from TCGA case TCGA-T2-A6X2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 82.2 years (30,013 days).
Specimen TCGA-T2-A6X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0634ad4-8c58-4da3-bdec-cf3fa2efa3a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T2-A6X2-10B (Blood Derived Normal), aliquot TCGA-T2-A6X2-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bf0feda-ce6d-468c-a3f8-3d773598c3ef

The open-access MAF lists 396 somatic variants for this specimen: 301 protein-altering or splice-affecting, 90 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 90, Nonsense Mutation 26, Splice Site 8, Intron 4, Frame Shift Del 3, Splice Region 2, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8245C>T p.Q2749* | Nonsense Mutation (SNP) | VAF 37/107 reads (35%) | catalogued as rs1135401925, COSV101204607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F9 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852233, CM940466, CM940467, CM960576, COSV54382023, COSV99496796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV99286712; called by muse, mutect2, varscan2
- ACSL5 | c.974G>C p.R325T (on ENST00000354273; = p.R381T on NM_016234.3) | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs1376788524, COSV100634761; called by muse, mutect2, varscan2
- ADAM33 | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs760699644, COSV100598056, COSV62934837; called by muse, mutect2
- ADAMTS12 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753119205, COSV61263306; called by muse, mutect2, varscan2
- ADAMTS18 | c.344C>A p.S115* | Nonsense Mutation (SNP) | VAF 85/239 reads (36%) | catalogued as COSV51399037, COSV99273948; called by muse, mutect2, varscan2
- ADGRB1 | c.1090A>G p.S364G | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1173022609, COSV100030238; called by muse, mutect2, varscan2
- ADGRB3 | c.2600G>C p.R867T | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV99486661; called by muse, mutect2, varscan2
- AHNAK | c.6784G>T p.E2262* | Nonsense Mutation (SNP) | VAF 227/780 reads (29%) | catalogued as COSV99949312; called by muse, mutect2, varscan2
- AK4 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519975; called by muse, mutect2, varscan2
- AKAP1 | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 55/217 reads (25%) | catalogued as COSV100028219; called by muse, varscan2
- AKAP6 | c.2860C>G p.H954D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55211048, COSV99803963; called by muse, mutect2, varscan2
- ALG1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.019); catalogued as COSV99275976; called by muse, mutect2, varscan2
- ANK2 | c.2901-1G>A p.X967_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100003816; called by muse, varscan2
- ANKRD11 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV56374078, COSV99968018; called by muse, mutect2, varscan2
- AOPEP | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV99469330; called by muse, mutect2, varscan2
- AP1B1 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100434777; called by muse, mutect2, varscan2
- ARFGEF1 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV99144276; called by muse, mutect2, varscan2
- ARHGAP11A | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100276936; called by muse, mutect2, varscan2
- ARHGAP25 | c.817G>C p.E273Q (on ENST00000409202 / NM_001007231.3; = p.E265Q on NM_014882.3) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV54901365; called by muse, mutect2, varscan2
- ARHGEF1 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100529181; called by muse, mutect2, varscan2
- ARID2 | c.4241G>A p.R1414K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV57602936, COSV57612118; called by muse, mutect2, varscan2
- ASNS | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99446750; called by muse, mutect2, varscan2
- ATAD3B | c.596G>A p.R199Q (on ENST00000308647; = p.R305Q on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs138300243; called by muse, mutect2, varscan2
- ATAT1 | c.980C>G p.P327R (on ENST00000376485; = p.P315R on NM_001031722.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99528161; called by muse, varscan2
- ATP11A | c.3316G>C p.E1106Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs781187093, COSV99369779; called by muse, mutect2, varscan2
- B2M | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV62564013; called by muse, mutect2, varscan2
- BDP1 | c.7321G>A p.E2441K | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV100703462; called by muse, mutect2, varscan2
- BHMT2 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99670281; called by muse, mutect2, varscan2
- BMP1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100110075; called by muse, mutect2, varscan2
- BMT2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1562915812, COSV99774689, COSV99774775; called by muse, mutect2, varscan2
- BRSK2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754262868, COSV100373095; called by muse, mutect2, varscan2
- C16orf46 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV100215376, COSV100215454; called by muse, mutect2, varscan2
- CACNA1C | c.2559G>A p.M853I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.577); catalogued as COSV100221775; called by muse, mutect2, varscan2
- CAPSL | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101274329, COSV68438284; called by muse, mutect2, varscan2
- CAPSL | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274330; called by muse, varscan2
- CAPSL | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1367715056, COSV68438728, COSV68439408; called by muse, varscan2
- CARF | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.022); catalogued as COSV100247855; called by muse, mutect2, varscan2
- CASK | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100587687; called by muse, mutect2, varscan2
- CASP8 | c.697C>T p.R233W (on ENST00000432109 / NM_033355.3; = p.R250W on NM_001228.4) | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760898260, COSV51846938; called by muse, mutect2, varscan2
- CCKBR | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as rs1221788949, COSV100582920, COSV58099964; called by muse, mutect2, varscan2
- CEP350 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV62605461; called by muse, mutect2, varscan2
- CFAP69 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 107/300 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100289973, COSV99062545; called by muse, mutect2, varscan2
- CHD7 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101418402; called by muse, mutect2, varscan2
- CHD8 | c.3744G>C p.Q1248H (on ENST00000646647 / NM_001170629.2; = p.Q969H on NM_020920.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101303204; called by muse, mutect2, varscan2
- CHRNB1 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100043761; called by muse, mutect2, varscan2
- CNGA4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs749126452, COSV99792456; called by muse, mutect2, varscan2
- CNOT1 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100409942, COSV100409948; called by muse, mutect2, varscan2
- COX14 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs368516862; called by muse, mutect2, varscan2
- CREBBP | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271647; called by muse, mutect2, varscan2
- CSTB | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99376983; called by muse, mutect2, varscan2
- CUL2 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV101039281; called by muse, mutect2, varscan2
- DCAF11 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV100386834, COSV100386913; called by muse, mutect2, varscan2
- DCN | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50010079; called by muse, mutect2, varscan2
- DDIAS | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV61272958; called by muse, mutect2, varscan2
- DIDO1 | c.4293G>C p.E1431D | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.268); catalogued as COSV99826922; called by muse, mutect2, varscan2
- DNAH17 | c.11344G>C p.E3782Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.599); catalogued as COSV101103256; called by muse, mutect2, varscan2
- DNAH17 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as COSV101103257; called by muse, mutect2, varscan2
- DNMBP | c.3381G>C p.K1127N | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144358; called by muse, mutect2, varscan2
- DPP10 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100071083; called by muse, mutect2, varscan2
- DRP2 | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100872047; called by muse, mutect2, varscan2
- DSG2 | c.1593C>G p.F531L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99853502; called by muse, mutect2, varscan2
- DSP | c.6187C>T p.R2063W | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs374090050, COSV101131684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECM1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV100682241; called by muse, mutect2, varscan2
- EHBP1 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.424); catalogued as COSV50433543; called by muse, mutect2, varscan2
- EPHA10 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200157400, COSV100361671; called by muse, mutect2, varscan2
- EPHA2 | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV100626261; called by muse, mutect2, varscan2
- EPHA6 | c.3355C>A p.H1119N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101065259; called by muse, mutect2, varscan2
- ERCC2 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs757100147, COSV101228751; called by muse, mutect2, varscan2
- ERF | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99724819; called by muse, mutect2, varscan2
- ESAM | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV99632092; called by muse, mutect2, varscan2
- ETHE1 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV52679472; called by muse, mutect2, varscan2
- EVI5L | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV99563496; called by muse, mutect2
- EXOSC10 | c.2639A>G p.Y880C (on ENST00000376936 / NM_001001998.3; = p.Y855C on NM_002685.4) | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV100442842; called by muse, mutect2, varscan2
- EXOSC3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV100520500; called by muse, mutect2, varscan2
- FAM120C | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100070430; called by muse, mutect2, varscan2
- FAM83B | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV100174932, COSV60927308; called by muse, mutect2, varscan2
- FAN1 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100756072; called by muse, mutect2, varscan2
- FAS | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 266/880 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV100570875; called by muse, mutect2, varscan2
- FAS | c.444-1G>C p.X148_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as CS991510, COSV100570876, COSV58239475, COSV58240007; called by muse, mutect2, varscan2
- FBN2 | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as rs778988322, COSV52508315; called by muse, mutect2, varscan2
- FBXO45 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV61147233; called by muse, mutect2, varscan2
- FBXO7 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 83/310 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as CM131920, COSV99832888; called by muse, mutect2, varscan2
- FGA | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1442902741, COSV100120670; called by muse, mutect2, varscan2
- FKBP5 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV100616400; called by muse, mutect2, varscan2
- GASK1B | c.1347C>G p.I449M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99648064; called by muse, mutect2
- GNB3 | c.495G>A p.T165= | Splice Region (SNP) | VAF 35/120 reads (29%) | catalogued as rs781817983, COSV51837340; called by muse, mutect2, varscan2
- GNL2 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100895039; called by muse, mutect2, varscan2
- GOLGA4 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs765556203, COSV100729129; called by muse, mutect2, varscan2
- GPR171 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99854444; called by muse, mutect2, varscan2
- GPRASP2 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 90/148 reads (61%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100176925; called by muse, mutect2, varscan2
- GREB1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1162600928, COSV99303657; called by muse, mutect2, varscan2
- GTF2H1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV99786601; called by muse, mutect2, varscan2
- GZMB | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs368712815, COSV53541697; called by muse, mutect2, varscan2
- H2AC14 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100297676; called by muse, mutect2, varscan2
- H2BC8 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV55126393, COSV99773363; called by muse, mutect2, varscan2
- HAND1 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99164011; called by muse, mutect2, varscan2
- HERC2 | c.12895C>A p.Q4299K | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV99876423; called by muse, mutect2, varscan2
- HLA-C | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66119743; called by mutect2, varscan2
- HMX2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs1324869911, COSV100378845; called by muse, mutect2, varscan2
- HPCAL1 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100324212; called by muse, mutect2, varscan2
- HUWE1 | c.4889A>G p.Y1630C | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99473997; called by muse, mutect2, varscan2
- IFT80 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.177); catalogued as COSV100425093; called by muse, mutect2, varscan2
- IGHV2-5 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs1555425537; called by muse, mutect2, varscan2
- IGHV4-39 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs757989989; called by muse, mutect2, varscan2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by muse, mutect2, varscan2
- IKBKB | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100645818; called by muse, mutect2, varscan2
- IPO11 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100321342; called by muse, mutect2, varscan2
- IQGAP2 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99167925; called by muse, mutect2, varscan2
- IRF2 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101165763; called by muse, mutect2
- IRF7 | c.312G>C p.W104C (on ENST00000397566; = p.W91C on NM_001572.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99213338; called by muse, mutect2
- ITGA2 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1369711141, COSV99671491; called by muse, mutect2, varscan2
- KIAA1109 | c.7979G>T p.R2660I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52686380, COSV99173834; called by muse, mutect2, varscan2
- KIAA1614 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as COSV100851238; called by muse, mutect2, varscan2
- KIAA1841 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV99693721, COSV99694183; called by muse, mutect2, varscan2
- KIF20B | c.4680+2T>G p.X1560_splice (on ENST00000371728 / NM_001284259.2; = p.X1520_splice on NM_016195.4) | Splice Site (SNP) | VAF 55/151 reads (36%) | catalogued as COSV99590635; called by muse, mutect2, varscan2
- KIF26B | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV101314153; called by muse, mutect2, varscan2
- KLHL2 | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99900272; called by muse, mutect2, varscan2
- KMT2A | c.6143G>T p.G2048V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100629700; called by muse, mutect2, varscan2
- KPNA1 | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100724373, COSV60268932; called by muse, varscan2
- LIG4 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100800049; called by muse, mutect2, varscan2
- LLGL2 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99390424; called by muse, mutect2, varscan2
- LOXL3 | c.2029C>A p.Q677K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99239914; called by muse, mutect2, varscan2
- LRP1B | c.10607G>C p.G3536A | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV101260116, COSV67257855, COSV67274990; called by muse, mutect2, varscan2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- LSAMP | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100372617; called by muse, mutect2, varscan2
- LUZP4 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs781918038, COSV100904879, COSV64219278; called by muse, mutect2, varscan2
- LYSMD1 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100925227; called by muse, mutect2, varscan2
- MAP1A | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100289151; called by muse, mutect2, varscan2
- MAP3K20 | c.1058G>C p.R353T | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100919608; called by muse, mutect2, varscan2
- MARCHF6 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV99930116; called by muse, mutect2, varscan2
- MB | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100704785; called by muse, mutect2, varscan2
- MED30 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs745941466, COSV52066113; called by muse, mutect2, varscan2
- MED31 | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99854630; called by muse, mutect2, varscan2
- METTL23 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100334236, COSV57970246; called by muse, mutect2, varscan2
- MFSD6 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.379); catalogued as COSV99855367; called by muse, mutect2, varscan2
- MNS1 | c.666G>C p.K222N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1406212854, COSV99549797; called by muse, mutect2, varscan2
- MOB1A | c.389C>A p.T130N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101247336; called by muse, mutect2
- MRTFB | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV100371764; called by muse, mutect2, varscan2
- MTMR6 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101110836; called by muse, mutect2, varscan2
- MTPAP | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99554289; called by muse, mutect2, varscan2
- MUC16 | c.39643C>G p.L13215V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.87); catalogued as rs1220833732, COSV101110069, COSV66695207; called by muse, mutect2, varscan2
- MUC16 | c.10460C>T p.S3487F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV67455233; called by muse, mutect2, varscan2
- MUS81 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100337377; called by muse, mutect2, varscan2
- MYH9 | c.5275-1G>A p.X1759_splice | Splice Site (SNP) | VAF 52/144 reads (36%) | catalogued as rs1292715916, COSV99339719; called by muse, mutect2, varscan2
- MYLK | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs771785615, COSV99051877; called by muse, mutect2, varscan2
- MYO5C | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV55902395, COSV99955350; called by muse, mutect2, varscan2
- MYOM1 | c.4162C>G p.H1388D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.267); catalogued as COSV99868131; called by muse, mutect2, varscan2
- NADK | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.598); catalogued as COSV100411034; called by muse, mutect2, varscan2
- NAV1 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs778690179, COSV99819564; called by muse, mutect2, varscan2
- NCOA6 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100750293; called by muse, mutect2, varscan2
- NDRG1 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.548); catalogued as COSV100106388; called by muse, mutect2, varscan2
- NEFM | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99647535; called by muse, mutect2, varscan2
- NIF3L1 | c.490G>A p.E164K (on ENST00000409020 / NM_001369444.1; = p.E137K on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.175); catalogued as COSV99626958; called by muse, mutect2, varscan2
- NISCH | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100617338; called by muse, mutect2, varscan2
- NLRC5 | c.3027C>A p.L1009= | Splice Region (SNP) | VAF 27/86 reads (31%) | catalogued as rs1379843387, COSV52655823, COSV99348108; called by muse, mutect2, varscan2
- NOL8 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100694672; called by muse, mutect2, varscan2
- NOVA2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54356108; called by muse, mutect2, varscan2
- NRP2 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV99785477; called by muse, mutect2, varscan2
- NRXN3 | c.1783C>T p.Q595* (on ENST00000557594 / NM_001272020.2; = p.Q1019* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55360483; called by muse, mutect2, varscan2
- NT5DC1 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100127197, COSV60312785; called by muse, varscan2
- NT5DC1 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100127202; called by muse, mutect2, varscan2
- NTN5 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99539551; called by muse, mutect2
- NUAK2 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100904148; called by muse, mutect2, varscan2
- NUDT12 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs1168418477, COSV50092084; called by muse, mutect2, varscan2
- NUMA1 | c.3410A>C p.Q1137P | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV100706559; called by muse, mutect2, varscan2
- NXF1 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53677266; called by muse, mutect2, varscan2
- OBSCN | c.6851G>C p.R2284P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV99483512; called by muse, mutect2, varscan2
- ODF2 | c.678G>A p.M226I (on ENST00000434106 / NM_153433.2; = p.M202I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV100654944; called by muse, mutect2, varscan2
- OR2T27 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV100788373, COSV61283443; called by muse, varscan2
- OR5D13 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100687016; called by muse, mutect2, varscan2
- OR8B3 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.323); catalogued as COSV100660431; called by muse, mutect2, varscan2
- OR9K2 | c.922T>A p.L308M (on ENST00000305377; = p.L286M on NM_001005243.1) | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100543910; called by muse, mutect2, varscan2
- ORC2 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99309716, COSV99309726; called by muse, mutect2, varscan2
- PASD1 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV100949569, COSV64855582; called by muse, mutect2, varscan2
- PATL1 | c.2254G>C p.D752H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100275204; called by muse, mutect2, varscan2
- PCDHB6 | c.2158G>T p.V720L | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50710738, COSV99170894; called by muse, mutect2, varscan2
- PCNT | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765585626, COSV100855988; called by muse, mutect2, varscan2
- PCNX2 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50789158, COSV50794299, COSV99269281; called by muse, mutect2, varscan2
- PCSK9 | c.766C>G p.Q256E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100135519; called by muse, varscan2
- PENK | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 82/159 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100152456; called by muse, mutect2, varscan2
- PKP3 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1346944150, COSV100230265; called by muse, mutect2, varscan2
- PLCB1 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100571924; called by muse, mutect2, varscan2
- PLEKHG3 | c.482C>T p.S161L (on ENST00000394691; = p.S217L on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs575204431, COSV99907046; called by muse, mutect2, varscan2
- PMS2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.156); catalogued as COSV56149941; called by muse, mutect2, varscan2
- POLQ | c.3305C>G p.S1102C | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99952842; called by muse, mutect2, varscan2
- PPFIA2 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100334981; called by muse, mutect2, varscan2
- PPP4C | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54221950; called by muse, mutect2, varscan2
- PREX2 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381541350, COSV55764923, COSV55804583; called by muse, mutect2, varscan2
- PRR7 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99445375, COSV99446482; called by muse, mutect2, varscan2
- PTPRB | c.3880G>C p.E1294Q | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99718735; called by muse, mutect2, varscan2
- PTPRU | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs761301664, COSV60527308; called by muse, mutect2, varscan2
- PUS7 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100708632; called by muse, mutect2, varscan2
- RAB11FIP5 | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753569888, COSV50247751; called by muse, varscan2
- RAB13 | c.325-1G>A p.X109_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100885282; called by muse, mutect2, varscan2
- RABEP1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as rs1567527738, COSV99336962; called by muse, mutect2, varscan2
- RAD51B | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101185383; called by muse, mutect2, varscan2
- RALGAPA1 | c.3107-1G>A p.X1036_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99355901; called by muse, mutect2
- RAP1GDS1 | c.1034G>A p.R345K (on ENST00000408927 / NM_001100427.2; = p.R346K on NM_021159.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV99216680, COSV99217322; called by muse, mutect2, varscan2
- RASAL3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100640331; called by muse, mutect2, varscan2
- RB1CC1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50243262, COSV99212808; called by muse, mutect2, varscan2
- RBM15B | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100082317; called by muse, mutect2, varscan2
- RBMS2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100008658; called by muse, mutect2, varscan2
- RELN | c.4794G>A p.M1598I | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV100634725; called by muse, mutect2, varscan2
- RETREG3 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99258889; called by muse, mutect2, varscan2
- RGPD2 | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV100553056, COSV100553112; called by mutect2, varscan2
- RIMBP2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1465657908, COSV55467681; called by muse, mutect2, varscan2
- ROS1 | c.5378C>G p.S1793* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100877645; called by muse, mutect2, varscan2
- RPE65 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV99254250; called by muse, mutect2, varscan2
- RSPO1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.84); catalogued as COSV100740690; called by muse, mutect2, varscan2
- SACS | c.8291C>T p.S2764L | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as CD1111487, COSV101207678; called by muse, mutect2, varscan2
- SAFB | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.112); catalogued as rs756589107, COSV52651292, COSV52652226, COSV52653358; called by muse, mutect2, varscan2
- SARM1 | c.1953G>C p.K651N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV99135032; called by muse, mutect2, varscan2
- SCGB3A1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV99485024; called by muse, mutect2
- SEL1L3 | c.3035C>G p.S1012* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | catalogued as COSV99341153; called by muse, mutect2, varscan2
- SETD1A | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV99353610; called by muse, mutect2, varscan2
- SF3B3 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100210168; called by muse, mutect2, varscan2
- SHKBP1 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99399343; called by muse, mutect2, varscan2
- SLC22A11 | c.1062C>G p.F354L | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100102645; called by muse, mutect2, varscan2
- SLC35F1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.55); catalogued as COSV64501836; called by muse, mutect2, varscan2
- SLU7 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV99775803; called by muse, varscan2
- SMAP1 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as COSV57637230; called by muse, mutect2, varscan2
- SMTN | c.1461A>C p.E487D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100294870; called by muse, mutect2, varscan2
- SNAPC1 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99359356; called by muse, mutect2, varscan2
- SNX12 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99339943; called by muse, mutect2, varscan2
- SP100 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV99894105; called by muse, mutect2, varscan2
- SPAG9 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100005825; called by muse, mutect2, varscan2
- SPATA31D1 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748427993, COSV100783024; called by muse, mutect2, varscan2
- SPATA7 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99248315; called by muse, mutect2, varscan2
- SPEN | c.10622C>T p.S3541F | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65269438; called by muse, mutect2, varscan2
- SPG7 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as COSV99244757; called by muse, mutect2, varscan2
- SPRED1 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 31/101 reads (31%) | catalogued as COSV54437864; called by muse, mutect2, varscan2
- SPTB | c.6942G>T p.K2314N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV99907047; called by muse, mutect2, varscan2
- SRRM1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100105073; called by muse, mutect2, varscan2
- SSH2 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as COSV99282896; called by muse, mutect2, varscan2
- STARD8 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1243717278, COSV99367545; called by muse, mutect2, varscan2
- STK10 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV99451301; called by muse, mutect2, varscan2
- STK19 | c.971C>T p.S324L (on ENST00000375333 / NM_032454.1; = p.S320L on NM_004197.1) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100941774; called by muse, mutect2, varscan2
- STOML2 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.362); catalogued as COSV99956908; called by muse, varscan2
- SYNE1 | c.8350G>A p.E2784K (on ENST00000367255 / NM_182961.4; = p.E2791K on NM_033071.3) | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99576362; called by muse, mutect2, varscan2
- SYNGAP1 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV99538927; called by muse, varscan2
- SYNGAP1 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99538929; called by muse, varscan2
- TAF1L | c.4900G>C p.E1634Q | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54258335, COSV99645324; called by muse, mutect2, varscan2
- TAP1 | c.1793G>C p.G598A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100841299; called by muse, mutect2
- TBX19 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs763177941, COSV100892400; called by muse, mutect2, varscan2
- TCOF1 | c.3149C>T p.S1050L (on ENST00000377797 / NM_001135243.1; = p.S973L on NM_000356.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100078235; called by muse, mutect2, varscan2
- TCTN1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.725); catalogued as COSV100886233; called by muse, mutect2, varscan2
- TEX10 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV100887950; called by muse, mutect2, varscan2
- TFAP2A | c.886G>C p.E296Q (on ENST00000482890; = p.E288Q on NM_001032280.3) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100117152; called by muse, mutect2, varscan2
- TGFBR2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM064336, COSV55442699; called by muse, mutect2, varscan2
- TGM6 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV99172612; called by muse, mutect2, varscan2
- THAP1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 66/204 reads (32%) | catalogued as CM106017, COSV54273904; called by muse, mutect2, varscan2
- THAP9 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs779461904, COSV56356024; called by muse, mutect2, varscan2
- TIAM2 | c.2004G>C p.K668N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019948; called by muse, mutect2, varscan2
- TLR8 | c.1933G>A p.D645N (on ENST00000218032 / NM_138636.5; = p.D663N on NM_016610.4) | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV54318890; called by muse, mutect2, varscan2
- TMEM138 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as COSV99582664; called by muse, mutect2, varscan2
- TMEM186 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.131); catalogued as COSV99191179; called by muse, mutect2, varscan2
- TMEM223 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV99585435; called by muse, mutect2, varscan2
- TMEM87B | c.1565C>A p.S522* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as COSV99314622; called by muse, mutect2, varscan2
- TNKS1BP1 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100836245; called by muse, mutect2, varscan2
- TOP2A | c.4357C>G p.Q1453E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV101352293, COSV101352316; called by muse, mutect2, varscan2
- TOPBP1 | c.1151G>C p.G384A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); catalogued as COSV99605773; called by muse, mutect2, varscan2
- TPP2 | c.621-1G>C p.X207_splice | Splice Site (SNP) | VAF 59/204 reads (29%) | catalogued as COSV101060398; called by muse, mutect2, varscan2
- TRIM33 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.136); catalogued as COSV100635709; called by muse, mutect2, varscan2
- TRIM54 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149008031; called by muse, mutect2, varscan2
- TRPM5 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV99330489; called by muse, mutect2, varscan2
- TRPM7 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100540257; called by muse, mutect2, varscan2
- TTC22 | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100988183; called by muse, mutect2, varscan2
- TTN | c.85414G>A p.D28472N (on ENST00000591111; = p.D21048N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | PolyPhen probably damaging (0.998); catalogued as rs1186226559, COSV100627123; called by muse, mutect2, varscan2
- TTN | c.77683G>A p.E25895K (on ENST00000591111; = p.E18471K on NM_003319.4) | Missense Mutation (SNP) | VAF 72/196 reads (37%) | PolyPhen possibly damaging (0.555); catalogued as rs745974517, COSV59926807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP2 | c.2489C>G p.S830* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99428304; called by muse, mutect2, varscan2
- UFSP1 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53815424, COSV99574513; called by muse, mutect2, varscan2
- UNC5C | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV101498014, COSV71660622; called by muse, mutect2, varscan2
- USP10 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs199959868; called by muse, mutect2, varscan2
- USP28 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV99136462; called by muse, mutect2, varscan2
- USP9X | c.4361G>C p.G1454A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV100200011; called by muse, mutect2, varscan2
- VPS13A | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV62434697, COSV62437651; called by muse, mutect2, varscan2
- VPS37D | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as rs782323818, COSV100265337; called by muse, mutect2, varscan2
- WASF3 | c.381G>C p.Q127H | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.308); catalogued as COSV100099407; called by muse, mutect2, varscan2
- XAF1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV100695160; called by muse, mutect2, varscan2
- XIRP2 | c.8374G>C p.E2792Q (on ENST00000628543; = p.E2967Q on NM_152381.6) | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV99746731; called by muse, mutect2, varscan2
- ZBTB1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100704223; called by muse, mutect2, varscan2
- ZBTB17 | c.2252C>A p.A751E | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs772879780, COSV100999062, COSV65272421; called by muse, mutect2, varscan2
- ZBTB7C | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs200790874, COSV100134587; called by muse, mutect2, varscan2
- ZC3HAV1L | c.761-1G>C p.X254_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99312988; called by muse, mutect2, varscan2
- ZCCHC8 | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100288827; called by muse, mutect2, varscan2
- ZFP42 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100479136, COSV58816339; called by muse, mutect2, varscan2
- ZNF107 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.618); catalogued as COSV61332630; called by muse, mutect2, varscan2
- ZNF28 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs746829005, COSV60424552; called by muse, mutect2, varscan2
- ZNF493 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs150051672; called by muse, mutect2, varscan2
- ZNF609 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100441706; called by muse, mutect2, varscan2
- ZNF709 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1363601768, COSV101172277; called by muse, mutect2, varscan2
- ZNF790 | c.1119A>T p.K373N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100764870, COSV63213524; called by muse, mutect2, varscan2
- ZNF800 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV99758175; called by muse, mutect2, varscan2
- B2M | c.121_122del p.N41Ffs*15 | Frame Shift Del (DEL) | VAF 73/265 reads (28%) | called by mutect2, pindel, varscan2
- BIRC6 | c.10474_10476del p.S3492del | In Frame Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- CD177 | c.825G>C p.K275N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KANK3 | c.2038_2039del p.Q680Efs*7 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3799dup p.D1267Gfs*24 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- NUFIP2 | c.804_814del p.K269Sfs*11 | Frame Shift Del (DEL) | VAF 53/252 reads (21%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1092C>T p.I364= | Silent (SNP) | VAF 58/221 reads (26%) | catalogued as COSV62324846; called by muse, mutect2, varscan2
- ABCC5 | c.2259G>A p.V753= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs771695920, COSV99657489; called by muse, mutect2, varscan2
- AMZ1 | c.1104C>A p.L368= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100406454; called by muse, mutect2, varscan2
- BBS7 | c.1368C>G p.L456= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99145063; called by muse, mutect2, varscan2
- BCL6 | c.609C>T p.V203= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99216003; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4173C>G p.L1391= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100863917; called by muse, mutect2, varscan2
- C17orf58 | c.168C>G p.L56= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs781983684, COSV100558746; called by muse, mutect2, varscan2
- CAMKK1 | c.1089G>A p.R363= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs772298969, COSV99340522; called by muse, mutect2, varscan2
- CASKIN2 | c.2721G>A p.L907= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100050856; called by muse, mutect2
- CCDC124 | c.600C>G p.L200= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs780837327, COSV101506511; called by muse, mutect2, varscan2
- CCDC88B | c.384C>G p.L128= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs1323253615, COSV100105857; called by muse, mutect2, varscan2
- CD93 | c.798C>T p.F266= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as COSV99849525; called by muse, mutect2, varscan2
- CDC6 | c.1176T>C p.D392= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as COSV99266665; called by muse, mutect2, varscan2
- CHCHD1 | c.234G>C p.A78= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100863420; called by muse, mutect2, varscan2
- CHML | c.1800C>T p.I600= | Silent (SNP) | VAF 58/169 reads (34%) | catalogued as COSV100087759; called by muse, mutect2, varscan2
- CHST9 | c.297C>G p.L99= | Silent (SNP) | VAF 86/312 reads (28%) | catalogued as COSV99410844; called by muse, mutect2, varscan2
- COL18A1 | c.1722C>T p.V574= (on ENST00000359759 / NM_130444.3; = p.V339= on NM_030582.4) | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs745792462, COSV100700928; called by muse, mutect2, varscan2
- COL7A1 | c.6006C>T p.R2002= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as rs200826090, COSV100097518; called by muse, mutect2, varscan2
- CPNE6 | c.1617C>T p.I539= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV53742611; called by muse, mutect2, varscan2
- CRNN | c.84C>T p.L28= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV99664336; called by muse, mutect2, varscan2
- CUX2 | c.1077G>A p.Q359= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99920605; called by muse, mutect2, varscan2
- DHX58 | c.240G>C p.L80= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99288459; called by muse, mutect2, varscan2
- DIS3L2 | c.2031G>C p.S677= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV99807149; called by muse, mutect2, varscan2
- DNAH1 | c.4479C>T p.I1493= | Silent (SNP) | VAF 67/227 reads (30%) | catalogued as rs781400506, COSV101326915; called by muse, mutect2, varscan2
- EOLA1 | c.48C>G p.V16= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100828442; called by muse, mutect2, varscan2
- ERRFI1 | c.543C>T p.F181= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV101088262; called by muse, mutect2, varscan2
- FAT1 | c.13581C>T p.F4527= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs373825887; called by muse, mutect2, varscan2
- FBXL6 | c.96G>C p.P32= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100095605, COSV57351743; called by muse, mutect2
- FCN3 | c.180T>G p.G60= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99585502; called by muse, mutect2, varscan2
- FEZF2 | c.192C>T p.L64= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99334989; called by muse, varscan2
- FOXD1 | c.537C>T p.L179= | Silent (SNP) | VAF 93/262 reads (35%) | catalogued as COSV100197741; called by muse, mutect2, varscan2
- FOXG1 | c.954C>T p.H318= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as COSV100487036; called by muse, mutect2, varscan2
- GABPA | c.964C>T p.L322= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV61397556; called by muse, mutect2, varscan2
- GLI1 | c.174G>A p.E58= | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as COSV99954607; called by muse, mutect2, varscan2
- GRIK1 | c.2475A>G p.K825= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV100517765; called by muse, mutect2, varscan2
- ITPR3 | c.7509C>T p.I2503= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as rs767020507, COSV100951969; called by muse, mutect2, varscan2
- KCNH3 | c.288G>A p.E96= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99235718; called by muse, mutect2
- KIT | c.1227G>C p.V409= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99855191; called by muse, mutect2, varscan2
- KPTN | c.417C>G p.L139= | Silent (SNP) | VAF 77/277 reads (28%) | catalogued as COSV54550194, COSV99645888; called by muse, mutect2, varscan2
- LCT | c.3276G>A p.R1092= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV51544088; called by muse, mutect2, varscan2
- METTL4 | c.1371C>G p.L457= | Silent (SNP) | VAF 69/182 reads (38%) | catalogued as COSV60602895; called by muse, mutect2, varscan2
- MLC1 | c.972C>T p.I324= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100286540; called by muse, mutect2, varscan2
- MTHFR | c.909G>A p.V303= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100928236; called by muse, mutect2, varscan2
- MTRF1 | c.636G>A p.Q212= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99520980; called by muse, mutect2, varscan2
- MYO16 | c.144G>A p.L48= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99194505; called by muse, mutect2, varscan2
- MYOF | c.474C>T p.D158= | Silent (SNP) | VAF 16/501 reads (3%) | catalogued as rs1032027681, COSV100826088; called by muse, mutect2
- NDUFS2 | c.1350C>T p.I450= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as COSV99248432; called by muse, mutect2, varscan2
- NEU3 | c.522G>A p.V174= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as COSV99579723; called by muse, mutect2, varscan2
- NHLRC2 | c.255C>T p.F85= | Silent (SNP) | VAF 48/161 reads (30%) | catalogued as COSV100800472; called by muse, mutect2, varscan2
- NINL | c.3864G>A p.L1288= | Silent (SNP) | VAF 123/422 reads (29%) | catalogued as rs1298248030, COSV53998310; called by muse, mutect2, varscan2
- NSFL1C | c.969C>T p.L323= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99401589; called by muse, mutect2, varscan2
- NUDT10 | c.132C>G p.R44= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100726843; called by muse, mutect2, varscan2
- ODF2 | c.1566C>G p.L522= (on ENST00000434106 / NM_153433.2; = p.L498= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV63548871; called by muse, mutect2, varscan2
- OR2M4 | c.93C>T p.V31= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as rs1411641094, COSV60709441; called by muse, mutect2, varscan2
- OR5B12 | c.300C>T p.F100= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1165084500, COSV100222535; called by muse, mutect2, varscan2
- PADI3 | c.1443C>G p.P481= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV64933839; called by muse, mutect2, varscan2
- PAMR1 | c.1689C>T p.I563= (on ENST00000619888 / NM_001001991.3; = p.I580= on NM_015430.4) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99553181; called by muse, mutect2, varscan2
- PARP6 | c.1380G>A p.R460= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99536350; called by muse, mutect2, varscan2
- PCDHGA12 | c.987G>A p.A329= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as COSV52766412; called by muse, mutect2, varscan2
- PEX5L | c.1794C>G p.L598= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as rs755746984, COSV55838391, COSV99829752, COSV99829781; called by muse, mutect2, varscan2
- PLEKHG4B | c.3474C>T p.P1158= (on ENST00000283426; = p.P1514= on NM_052909.5) | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs777599657, COSV52051080; called by muse, mutect2, varscan2
- PSME1 | c.315C>T p.N105= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV99246474; called by muse, mutect2, varscan2
- RARA | c.1269G>A p.L423= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- RCE1 | c.159C>G p.L53= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs755924350, COSV100547178; called by muse, mutect2, varscan2
- RGMA | c.264G>A p.R88= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV61235228; called by muse, mutect2, varscan2
- RYR3 | c.5097G>C p.L1699= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as COSV101214197; called by muse, mutect2, varscan2
- SIL1 | c.564G>A p.L188= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV99498496; called by muse, mutect2, varscan2
- SIRT7 | c.522G>A p.L174= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs976501937, COSV100155713; called by muse, mutect2, varscan2
- SLA | c.675C>T p.F225= (on ENST00000338087 / NM_001045556.3; = p.F265= on NM_006748.4) | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV99602881; called by muse, mutect2, varscan2
- SLX4IP | c.1002G>A p.L334= | Silent (SNP) | VAF 62/173 reads (36%) | catalogued as COSV100570788; called by muse, mutect2, varscan2
- SPEG | c.5613C>T p.F1871= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100405493; called by muse, mutect2, varscan2
- SYNDIG1 | c.348C>T p.I116= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as rs752814825, COSV100965413; called by muse, mutect2, varscan2
- TBC1D31 | c.552C>T p.L184= | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as COSV99783162; called by muse, mutect2, varscan2
- TF | c.1191C>T p.I397= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs776533532, COSV53917959, COSV53918224; called by muse, mutect2, varscan2
- TMC2 | c.1774C>T p.L592= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100727940; called by muse, mutect2, varscan2
- TMEM104 | c.1350G>A p.Q450= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100120952; called by muse, mutect2, varscan2
- TMEM117 | c.936G>A p.L312= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1311827583, COSV99863546; called by muse, mutect2, varscan2
- TMEM63A | c.2313G>A p.Q771= | Silent (SNP) | VAF 73/212 reads (34%) | catalogued as COSV99689185; called by muse, mutect2, varscan2
- TNNI3 | c.594G>C p.L198= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99403002; called by muse, mutect2, varscan2
- TOP2B | c.4863T>C p.D1621= (on ENST00000264331 / NM_001330700.2; = p.D1616= on NM_001068.3) | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV99980223; called by muse, mutect2, varscan2
- TRANK1 | c.7206C>T p.I2402= | Silent (SNP) | VAF 79/146 reads (54%) | catalogued as COSV100084517; called by muse, mutect2, varscan2
- TRPM7 | c.2253G>A p.L751= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100540256; called by muse, mutect2, varscan2
- TSHZ1 | c.2919C>T p.N973= (on ENST00000580243 / NM_001308210.2; = p.N928= on NM_005786.6) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs771320123, COSV59012368; called by muse, mutect2, varscan2
- TTC3 | c.2079G>A p.K693= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100695181, COSV61293060; called by muse, mutect2, varscan2
- WDR31 | c.78A>G p.K26= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV100516773; called by muse, mutect2, varscan2
- XRRA1 | c.1677G>A p.K559= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100370067; called by muse, mutect2, varscan2
- ZDHHC3 | c.561C>T p.L187= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV56103424; called by muse, mutect2, varscan2
- ZFP30 | c.232C>T p.L78= | Silent (SNP) | VAF 105/377 reads (28%) | catalogued as COSV100666068; called by muse, mutect2, varscan2
- ZNF518B | c.2448G>A p.V816= | Silent (SNP) | VAF 63/175 reads (36%) | catalogued as rs963839335, COSV100456845; called by muse, mutect2, varscan2
- ZNF682 | c.96G>A p.V32= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as COSV100653343; called by muse, mutect2, varscan2
- BAIAP2 | c.1535+2429C>A | Intron (SNP) | VAF 51/127 reads (40%) | catalogued as COSV100348724; called by muse, mutect2, varscan2
- CLEC2D | c.461+161C>T | Intron (SNP) | VAF 40/149 reads (27%) | catalogued as rs377194446; called by muse, mutect2, varscan2
- DST | c.4297-3712C>G | Intron (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99759385; called by muse, mutect2, varscan2
- NACA | c.70+3053C>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100771599; called by muse, mutect2, varscan2
- ZNF137P | n.1578T>C | RNA (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
